Somatic mutation profile of tumor specimen ALCH-B1YL-TTP1-A (aliquot ALCH-B1YL-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1YL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,812 days).
Specimen ALCH-B1YL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d098df16-4d7f-438a-b022-39eb73d4b3fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YL-NB1-A (Blood Derived Normal), aliquot ALCH-B1YL-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b19684-770b-47b7-aec4-8a38148bc846

The open-access MAF lists 72 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Nonsense Mutation 4, Intron 3, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8296C>G p.Q2766E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.228); catalogued as COSV99081660; called by muse, varscan2
- ANPEP | c.1800C>A p.Y600* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | catalogued as COSV55596383; called by muse, mutect2
- B9D2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54684840; called by muse, mutect2
- CCDC178 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV55761695; called by mutect2, varscan2
- COL14A1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as rs1405475821; called by muse, mutect2
- EMX2 | c.332C>G p.S111W | Missense Mutation (SNP) | VAF 18/511 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1426142917, COSV71294387, COSV71294478; called by muse, mutect2
- GLIS3 | c.1772G>A p.S591N | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs1456570482; called by muse, mutect2
- KASH5 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1489083642, COSV101483374; called by muse, mutect2
- KEAP1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50282588, COSV50307610; called by muse, mutect2
- MYH4 | c.5575G>C p.E1859Q | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV55119141; called by muse, mutect2
- ODF3L1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200727526; called by muse, mutect2
- OR10T2 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.148); catalogued as COSV57781214; called by muse, mutect2
- PARG | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV101312605; called by muse, mutect2
- PPP1R16B | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV55378127, COSV55385570; called by muse, mutect2
- SLX4 | c.5411A>G p.H1804R | Missense Mutation (SNP) | VAF 29/462 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs956924993; called by muse, mutect2
- TSHR | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 20/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM057217; called by muse, mutect2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- VCL | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV53012505; called by muse, mutect2
- YY1AP1 | c.433G>C p.E145Q (on ENST00000295566 / NM_139118.2; = p.E68Q on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55121496; called by muse, mutect2
- ZDBF2 | c.5114C>G p.S1705C | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1481214952; called by muse, mutect2, varscan2
- AP000721.1 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); called by muse, mutect2
- ARHGEF3 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2
- C5orf51 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | called by muse, varscan2
- CCDC38 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHPF | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2
- CHST1 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- COL1A2 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 21/513 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- COL5A1 | c.3241G>C p.G1081R | Missense Mutation (SNP) | VAF 30/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A3 | c.5213T>A p.L1738Q | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DBP | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- DLGAP2 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2
- FAM71E2 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2
- FOXP1 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- HNRNPUL1 | c.647-1G>A p.X216_splice | Splice Site (SNP) | VAF 35/356 reads (10%) | called by muse, mutect2, varscan2
- ICE1 | c.1586A>T p.E529V | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- IPCEF1 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- ITGA5 | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- KCNJ1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); called by muse, mutect2
- KCNT2 | c.2672G>T p.S891I | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- KHDC4 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2
- KIAA1109 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LAMA1 | c.8941C>G p.Q2981E | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.088); called by muse, mutect2
- LGALS9 | c.662C>T p.P221L (on ENST00000395473 / NM_009587.3; = p.P189L on NM_002308.4) | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- NID2 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- NIPBL | c.5357T>C p.I1786T | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- PDE7B | c.1265G>A p.R422K | Missense Mutation (SNP) | VAF 34/581 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.015); called by muse, mutect2
- PHF1 | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- PRSS12 | c.2192G>C p.R731T | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- RAPGEF2 | c.4184G>T p.R1395M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SKIV2L | c.3566C>G p.S1189* | Nonsense Mutation (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- SNTA1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TENM3 | c.2540C>A p.S847Y | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TG | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- TICRR | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ZNF667 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2, varscan2
- ZNF865 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT deleterious (0.02); called by muse, mutect2
- ABCC8 | c.1722C>T p.S574= | Silent (SNP) | VAF 14/361 reads (4%) | catalogued as rs1471889041, COSV56854279; called by muse, mutect2
- AKR1C3 | c.45C>T p.F15= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as rs1280270013, COSV65910604, COSV65911199; called by muse, varscan2
- ANTXR1 | c.93C>G p.R31= | Silent (SNP) | VAF 46/581 reads (8%) | called by muse, mutect2
- FOXP2 | c.339G>T p.L113= | Silent (SNP) | VAF 29/476 reads (6%) | called by muse, mutect2
- HSD17B12 | c.555G>A p.L185= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as COSV53501673; called by muse, mutect2, varscan2
- NUP205 | c.5301C>A p.L1767= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV53654314; called by muse, mutect2
- PCDHA6 | c.2307C>T p.L769= | Silent (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- SI | c.3159C>A p.T1053= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- SLC24A5 | c.213C>A p.I71= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- TCF7L1 | c.114G>T p.L38= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- TNXB | c.9186G>A p.P3062= (on ENST00000647633; = p.P2815= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs761523934; called by muse, mutect2
- ZIC1 | c.708C>A p.A236= | Silent (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- AL359922.1 | c.348-35294C>T | Intron (SNP) | VAF 38/692 reads (5%) | catalogued as CM112061, CM112062, CS021185, COSV64265217, COSV64265629, COSV64269377; called by muse, mutect2
- CLSTN3 | c.2528-711C>T | Intron (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- FAM219A | c.-13G>T | 5'UTR (SNP) | VAF 16/94 reads (17%) | catalogued as rs780915027; called by muse, mutect2, varscan2
- IAPP | c.-15-16G>T | Intron (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
